Somatic mutation profile of tumor specimen 0DRZIX from CCDI case PBCHJE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.9 years (3,629 days).
Specimen 0DRZIX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe29c4cc-fff2-4c2c-b2af-b50f9bf2728d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRZJI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2159288-464f-450d-a036-5aa799fab195

The open-access MAF lists 43 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, 3'UTR 3, Frame Shift Del 3, Intron 3, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD1 | c.4039G>A p.V1347M | Missense Mutation (SNP) | VAF 139/624 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs757223796; called by muse, mutect2, varscan2
- CHD4 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 106/875 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); catalogued as rs761102450, COSV100538907, COSV58914240; called by muse, mutect2, varscan2
- DHX34 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 168/596 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs199965702; called by muse, mutect2, varscan2
- FAM207A | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 68/498 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.519); catalogued as rs768504644; called by muse, mutect2, varscan2
- FAM50B | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 162/650 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs373712054; called by muse, mutect2, varscan2
- OR2W3 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 61/445 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV64455957; called by muse, mutect2, varscan2
- PADI1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 208/506 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs144468100; called by muse, mutect2, varscan2
- RECK | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 270/667 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.511); catalogued as rs202116020, COSV65034487; called by muse, mutect2, varscan2
- SEMA4A | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 370/1012 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs756270130; called by muse, mutect2, varscan2
- SLC26A8 | c.2118_2120del p.R707del | In Frame Del (DEL) | VAF 71/505 reads (14%) | catalogued as rs751695953; called by pindel, varscan2
- SPG7 | c.2045G>A p.R682H (on ENST00000268704; = p.R689H on NM_003119.4) | Missense Mutation (SNP) | VAF 194/693 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs148199060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSTD1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 187/787 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57040019; called by muse, mutect2, varscan2
- WNT3A | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 34/435 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as rs1253254692; called by muse, mutect2
- ARHGEF10L | c.3202G>T p.V1068F | Missense Mutation (SNP) | VAF 118/809 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CCDC24 | c.256del p.R86Gfs*49 | Frame Shift Del (DEL) | VAF 209/927 reads (23%) | called by mutect2, pindel, varscan2
- CEP250 | c.6977G>T p.S2326I | Missense Mutation (SNP) | VAF 92/361 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- DENND2B | c.1831del p.R611Afs*23 | Frame Shift Del (DEL) | VAF 80/560 reads (14%) | called by mutect2, pindel, varscan2
- ELAPOR1 | c.1042-3C>A | Splice Region (SNP) | VAF 152/624 reads (24%) | called by muse, mutect2, varscan2
- OR8H1 | c.678A>C p.K226N | Missense Mutation (SNP) | VAF 459/1268 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- PASD1 | c.2132G>T p.C711F | Missense Mutation (SNP) | VAF 15/404 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2
- RAPGEF1 | c.1197C>G p.N399K | Missense Mutation (SNP) | VAF 95/731 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RNLS | c.368-1G>T p.X123_splice | Splice Site (SNP) | VAF 275/347 reads (79%) | called by muse, mutect2, varscan2
- TMCC1 | c.1633del p.A545Pfs*30 (on ENST00000393238 / NM_001349268.2; = p.A221Pfs*30 on NM_015008.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 341/915 reads (37%) | called by mutect2, pindel, varscan2
- TTN | c.73482G>T p.W24494C (on ENST00000591111; = p.W17070C on NM_003319.4) | Missense Mutation (SNP) | VAF 34/1012 reads (3%) | PolyPhen benign (0.04); called by muse, mutect2
- USP14 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 229/592 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP28 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 86/648 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- VPS13A | c.4715dup p.N1572Kfs*2 | Frame Shift Ins (INS) | VAF 251/740 reads (34%) | called by pindel, varscan2
- ZNF414 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 145/550 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ZP2 | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 179/727 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CACNA1D | c.6087C>T p.P2029= (on ENST00000350061 / NM_001128840.3; = p.P2049= on NM_000720.4) | Silent (SNP) | VAF 55/380 reads (14%) | catalogued as rs746231607, COSV55450246; called by muse, mutect2, varscan2
- CARD11 | c.1116G>A p.L372= | Silent (SNP) | VAF 64/532 reads (12%) | called by mutect2, varscan2
- CILK1 | c.1302T>C p.S434= (on ENST00000350082 / NM_001375397.1; = p.S427= on NM_014920.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 459/1064 reads (43%) | called by muse, mutect2, varscan2
- EPPK1 | c.14823C>T p.I4941= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs782227916; called by mutect2, varscan2
- NCOR2 | c.3621C>T p.S1207= | Silent (SNP) | VAF 139/426 reads (33%) | called by muse, mutect2, varscan2
- SLC26A4 | c.1755G>A p.L585= | Silent (SNP) | VAF 556/1062 reads (52%) | called by muse, mutect2, varscan2
- ZNF586 | c.792C>T p.C264= | Silent (SNP) | VAF 153/1068 reads (14%) | catalogued as rs1330609546, COSV66972461; called by muse, mutect2, varscan2
- AK2 | c.*1025C>A | 3'UTR (SNP) | VAF 59/377 reads (16%) | called by muse, mutect2, varscan2
- CNTN4 | c.56-23G>C | Intron (SNP) | VAF 215/450 reads (48%) | catalogued as COSV68568846; called by muse, mutect2, varscan2
- MINDY1 | c.*68G>A | 3'UTR (SNP) | VAF 101/186 reads (54%) | catalogued as rs947534164; called by muse, mutect2, varscan2
- PPP6R2 | c.2601-456C>G | Intron (SNP) | VAF 146/423 reads (35%) | catalogued as rs540407725; called by muse, mutect2, varscan2
- SIGLEC14 | c.*10G>A | 3'UTR (SNP) | VAF 171/441 reads (39%) | catalogued as rs760791932; called by muse, mutect2, varscan2
- TDRD9 | c.-43G>A | 5'UTR (SNP) | VAF 60/127 reads (47%) | called by muse, mutect2, varscan2
- VIPAS39 | c.735-26C>T | Intron (SNP) | VAF 106/310 reads (34%) | catalogued as rs780474740; called by muse, mutect2, varscan2
